Somatic mutation profile of tumor specimen MMRF_2098_1_BM_CD138pos (aliquot MMRF_2098_1_BM_CD138pos_T1_KHS5U_L08138) from MMRF case MMRF_2098, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.2 years (28,911 days).
Specimen MMRF_2098_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 407ca6db-c08d-481e-9d19-4023b3efa742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2098_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2098_1_PB_Whole_C2_KHS5U_L08139; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e9b5994-98b9-4739-b9d7-b6f13eaa820c

The open-access MAF lists 100 somatic variants for this specimen: 41 protein-altering or splice-affecting, 21 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 21, 3'UTR 19, Intron 11, Frame Shift Del 4, 5'UTR 4, Nonsense Mutation 3, 3'Flank 2, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRD1 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV53458006; called by muse, mutect2, varscan2
- CACNA2D3 | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368525499; called by muse, mutect2, varscan2
- CALML3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.157); catalogued as rs780155379; called by muse, mutect2, varscan2
- CAMSAP2 | c.3715C>T p.R1239W (on ENST00000236925 / NM_001297707.2; = p.R1228W on NM_203459.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199622691, COSV52667532; called by muse, mutect2, varscan2
- CCHCR1 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs751269045, COSV99456394; called by muse, mutect2, varscan2
- IGHV1-69 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 72/106 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs557675222; called by muse, varscan2
- IGHV1-69D | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1172981728; called by muse, varscan2
- IGHV2-70 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as rs372630587; called by muse, varscan2
- IGHV2-70 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751761340; called by muse, varscan2
- IGKV4-1 | c.199G>T p.G67* | Nonsense Mutation (SNP) | VAF 60/63 reads (95%) | catalogued as rs536959831; called by muse, varscan2
- KCNH2 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 135/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776485360, CD099232; called by muse, mutect2, varscan2
- MTHFR | c.1603del p.R535Gfs*9 | Frame Shift Del (DEL) | VAF 70/177 reads (40%) | catalogued as CM013905, COSV57171840; called by mutect2, pindel, varscan2
- MYO18B | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as rs759446365, COSV59139800; called by muse, varscan2
- NEK11 | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 172/513 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.324); catalogued as rs756151549; called by muse, mutect2, varscan2
- NPR2 | c.1937A>G p.K646R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV61039650; called by muse, mutect2, varscan2
- SH3GL1 | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 157/257 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1283524258; called by muse, mutect2, varscan2
- SLC6A16 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs905184108; called by muse, mutect2, varscan2
- SOGA3 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV64108243; called by muse, mutect2, varscan2
- SYNE2 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 121/235 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV100648161; called by muse, mutect2, varscan2
- TSHZ3 | c.2488G>A p.V830I | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs752492388, COSV53666413; called by muse, mutect2, varscan2
- USF3 | c.4120A>T p.M1374L | Missense Mutation (SNP) | VAF 160/250 reads (64%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV57075401; called by muse, mutect2, varscan2
- APOC2 | c.177_186del p.E60Tfs*5 | Frame Shift Del (DEL) | VAF 54/238 reads (23%) | called by mutect2, pindel, varscan2
- BRSK2 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BSCL2 | c.847_850del p.E283Sfs*52 | Frame Shift Del (DEL) | VAF 66/124 reads (53%) | called by pindel, varscan2
- CDC25C | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- COL19A1 | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYBB | c.1504A>G p.I502V | Missense Mutation (SNP) | VAF 54/56 reads (96%) | SIFT tolerated (0.43); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- EPHB2 | c.977C>G p.S326C | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- HIP1 | c.385-2_385-1del p.X129_splice | Splice Site (DEL) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 53/58 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- IGLV3-1 | c.62_73delinsG p.Y21* | Nonsense Mutation (DEL) | VAF 52/144 reads (36%) | called by pindel, varscan2*
- MYBL2 | c.187A>T p.N63Y | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYCL | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYLK | c.291T>A p.H97Q | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYOCD | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- NADSYN1 | c.821A>C p.D274A | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- P2RX5 | c.614+2T>C p.X205_splice | Splice Site (SNP) | VAF 58/123 reads (47%) | called by muse, mutect2, varscan2
- PCDH9 | c.2684C>G p.A895G | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHB16 | c.894del p.E300Kfs*4 | Frame Shift Del (DEL) | VAF 94/308 reads (31%) | called by mutect2, pindel, varscan2
- SP140 | c.2312A>G p.Y771C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1A | c.2646C>T p.D882= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100800382; called by muse, mutect2, varscan2
- CEP350 | c.6540A>T p.V2180= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- DLGAP3 | c.1035G>A p.P345= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs780932284; called by muse, mutect2, varscan2
- HPGD | c.480A>G p.G160= | Silent (SNP) | VAF 54/139 reads (39%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.207G>A p.G69= | Silent (SNP) | VAF 76/110 reads (69%) | catalogued as rs536100911; called by muse, varscan2
- IGHV2-70 | c.84T>C p.P28= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs377604349; called by muse, varscan2
- IGHV2-70 | c.81T>G p.G27= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs530772710; called by muse, varscan2
- KCNE1 | c.198C>A p.I66= | Silent (SNP) | VAF 117/211 reads (55%) | called by muse, mutect2, varscan2
- MRC2 | c.1701C>T p.F567= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs771782973; called by muse, mutect2, varscan2
- MTNR1A | c.622C>T p.L208= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as rs1229798843; called by muse, mutect2, varscan2
- NAALAD2 | c.936C>G p.A312= | Silent (SNP) | VAF 128/196 reads (65%) | catalogued as COSV58966852; called by muse, mutect2, varscan2
- RIOK2 | c.1311A>G p.G437= | Silent (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- RNF139 | c.843A>T p.I281= | Silent (SNP) | VAF 69/128 reads (54%) | called by muse, mutect2, varscan2
- SLAIN1 | c.303G>A p.P101= (on ENST00000466548; = p.P123= on NM_001242868.2) | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1080C>T p.I360= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs368974230; called by muse, mutect2, varscan2
- TAF15 | c.1513C>A p.R505= (on ENST00000605844 / NM_139215.3; = p.R502= on NM_003487.4) | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- TALDO1 | c.597A>C p.A199= | Silent (SNP) | VAF 89/377 reads (24%) | called by muse, mutect2, varscan2
- TC2N | c.1359C>T p.G453= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs759810034, COSV100563034; called by muse, mutect2, varscan2
- TENM1 | c.621G>A p.R207= | Silent (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- ZBTB1 | c.696T>C p.D232= | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV100704247; called by muse, mutect2
- ZMAT4 | c.153G>A p.R51= | Silent (SNP) | VAF 67/144 reads (47%) | catalogued as COSV52708023; called by muse, mutect2, varscan2
- AGTR2 | c.*718T>G | 3'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- ANKZF1 | c.1691+78T>C | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- ARL4A | chr7:12689736 A>G | 3'Flank (SNP) | VAF 64/221 reads (29%) | called by muse, mutect2, varscan2
- ASB1 | c.*260C>G | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2
- ATR | c.7762-1019A>T | Intron (SNP) | VAF 129/432 reads (30%) | catalogued as COSV53807750; called by muse, mutect2, varscan2
- ATXN2 | c.*21A>T | 3'UTR (SNP) | VAF 108/213 reads (51%) | called by muse, mutect2, varscan2
- CACNB4 | c.*1490T>A | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as rs1396555430, COSV52397389; called by muse, mutect2
- CHUK | c.*636G>T | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- CLK2 | c.*51C>G | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs368845441; called by muse, mutect2, varscan2
- CNTN4 | c.-6C>A | 5'UTR (SNP) | VAF 166/347 reads (48%) | catalogued as COSV68577110; called by muse, mutect2, varscan2
- COL27A1 | c.*685C>T | 3'UTR (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*8600C>T | 3'UTR (SNP) | VAF 41/98 reads (42%) | catalogued as rs922787695; called by muse, mutect2, varscan2
- DICER1 | c.*1295A>G | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by mutect2, varscan2
- E4F1 | c.1376-17G>A | Intron (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- FP565260.1 | c.*332C>T | 3'UTR (SNP) | VAF 31/36 reads (86%) | called by muse, mutect2, varscan2
- HPGD | c.*168G>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | catalogued as COSV56663523; called by muse, mutect2, varscan2
- HPGD | c.422-104T>C | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- IL16 | chr15:81309731 C>T | 3'Flank (SNP) | VAF 90/193 reads (47%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.573+2310A>C | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- MIR5195 | n.115A>G | RNA (SNP) | VAF 24/57 reads (42%) | catalogued as rs1233310183; called by muse, mutect2, varscan2
- MSR1 | c.1033+3263T>A | Intron (SNP) | VAF 20/42 reads (48%) | called by mutect2, varscan2
- NFIB | c.-35G>A | 5'UTR (SNP) | VAF 137/703 reads (19%) | called by muse, mutect2, varscan2
- NR2F2 | c.*2563A>C | 3'UTR (SNP) | VAF 83/158 reads (53%) | called by muse, mutect2, varscan2
- OR4F13P | n.506T>C | RNA (SNP) | VAF 93/373 reads (25%) | catalogued as rs917599635; called by muse, mutect2, varscan2
- OR51E1 | c.*631C>A | 3'UTR (SNP) | VAF 64/197 reads (32%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-5765C>T | Intron (SNP) | VAF 6/75 reads (8%) | catalogued as rs1239045722; called by muse, mutect2
- PMCH | c.-28T>C | 5'UTR (SNP) | VAF 52/130 reads (40%) | catalogued as rs1156296081; called by muse, mutect2, varscan2
- POLD4 | c.97+106C>T | Intron (SNP) | VAF 82/135 reads (61%) | called by muse, mutect2, varscan2
- PRDM6 | c.*59T>G | 3'UTR (SNP) | VAF 52/634 reads (8%) | called by muse, mutect2
- RFX4 | c.-44C>T | 5'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- RIN3 | c.2632-721C>T | Intron (SNP) | VAF 43/97 reads (44%) | catalogued as rs1286400074; called by muse, mutect2, varscan2
- RNF144B | c.*2586del | 3'UTR (DEL) | VAF 4/41 reads (10%) | catalogued as rs200074356; called by pindel, varscan2
- RNF144B | c.*2827G>A | 3'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- SPOCK3 | c.*883T>G | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2
- SV2C | c.*6294C>T | 3'UTR (SNP) | VAF 35/156 reads (22%) | catalogued as rs779530570; called by muse, mutect2, varscan2
- TRIM56 | c.*1089G>A | 3'UTR (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- TRPM8 | c.942+360C>G | Intron (SNP) | VAF 58/110 reads (53%) | called by muse, mutect2, varscan2
- USP36 | c.912-24T>G | Intron (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
